Somatic mutation profile of tumor specimen ALCH-B278-TTP1-A (aliquot ALCH-B278-TTP1-A-3-0-D-A774-36) from ALCHEMIST case ALCH-B278, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.6 years (20,303 days).
Specimen ALCH-B278-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bea6ffb6-8576-45c3-83ab-c2e65a85e8e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B278-NB1-A (Blood Derived Normal), aliquot ALCH-B278-NB1-A-1-0-D-A774-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44c4acbe-44cc-4609-89d9-fb344261f846

The open-access MAF lists 1,344 somatic variants for this specimen: 926 protein-altering or splice-affecting, 247 silent, 171 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 791, Silent 247, Intron 94, Nonsense Mutation 63, Frame Shift Del 28, Splice Site 23, RNA 23, 3'UTR 22, 5'UTR 21, Splice Region 18, 5'Flank 7, 3'Flank 4.

Variants (750 of 1,344; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 36/207 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs375338359, CM098494, COSV52690857, COSV52980226, COSV53438718; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1939C>A p.P647T (on ENST00000404938 / NM_001163941.2; = p.P202T on NM_178559.6) | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV51706555; called by muse, mutect2, varscan2
- ABCF1 | c.1030A>G p.T344A (on ENST00000326195 / NM_001025091.2; = p.T306A on NM_001090.3) | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs772382046; called by muse, mutect2, varscan2
- AC138647.1 | c.547C>A p.R183S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0); catalogued as COSV70194576; called by muse, varscan2
- ACP3 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1300953534; called by muse, mutect2, varscan2
- ADAM23 | c.2444G>A p.G815E | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52234132; called by muse, mutect2, varscan2
- ADAM30 | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs1374828553; called by muse, mutect2, varscan2
- ADAM7 | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs139013320, COSV51535893; called by muse, mutect2, varscan2
- ADAMTS16 | c.409del p.Q137Rfs*34 | Frame Shift Del (DEL) | VAF 62/149 reads (42%) | catalogued as COSV57004770; called by mutect2, pindel, varscan2
- AGXT2 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 46/289 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.225); catalogued as COSV104371018; called by muse, mutect2, varscan2
- AICDA | c.252G>C p.W84C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57564515; called by muse, mutect2, varscan2
- AL445989.1 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated, low confidence (0.05); catalogued as rs766509691; called by muse, mutect2, varscan2
- ALDH3A2 | c.1193C>G p.P398R | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51566241; called by muse, mutect2
- ALG2 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1201091336; called by muse, mutect2, varscan2
- ALX1 | c.694G>T p.G232C | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs960499054; called by muse, mutect2, varscan2
- ANAPC2 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100118983; called by muse, mutect2
- ANKRD30A | c.3496G>T p.G1166W (on ENST00000611781; = p.G1110W on NM_052997.2) | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV64622032; called by muse, mutect2
- ANKRD30A | c.3497G>T p.G1166V (on ENST00000611781; = p.G1110V on NM_052997.2) | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.879); catalogued as COSV64623876; called by muse, mutect2
- AREL1 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1421876397; called by muse, mutect2
- ARHGEF10 | c.1856A>G p.K619R (on ENST00000398564; = p.K594R on NM_014629.4) | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.039); catalogued as rs143500957; called by muse, mutect2
- ARHGEF17 | c.1940G>T p.G647V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV99735382; called by muse, mutect2, varscan2
- ARMC8 | c.1745A>G p.N582S (on ENST00000469044 / NM_001363941.2; = p.N568S on NM_015396.6) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV58622558; called by muse, mutect2, varscan2
- ARSF | c.571C>A p.L191I | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV63839216; called by muse, mutect2, varscan2
- ASB5 | c.276G>C p.Q92H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV99030449; called by muse, mutect2, varscan2
- ATG9B | c.1772A>T p.Q591L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.636); catalogued as COSV99871553; called by muse, mutect2, varscan2
- ATP1B4 | c.443G>T p.R148L (on ENST00000218008 / NM_001142447.3; = p.R144L on NM_012069.5) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV54312269, COSV54315433; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs782185133, COSV99314113; called by muse, mutect2
- ATRNL1 | c.3128G>A p.C1043Y | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58116661; called by mutect2, varscan2
- BNC1 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as COSV61759322; called by muse, mutect2, varscan2
- BNC1 | c.1001G>A p.R334K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.104); catalogued as rs781449799; called by muse, mutect2, varscan2
- BOD1L1 | c.8356G>T p.D2786Y | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV99240139; called by muse, mutect2, varscan2
- BTG2 | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV99305845; called by muse, mutect2, varscan2
- C8orf74 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs374916501; called by muse, mutect2, varscan2
- CA3 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557237110, COSV53409536, COSV53411192; called by muse, mutect2, varscan2
- CACNA2D1 | c.3233A>C p.N1078T (on ENST00000356253 / NM_001366867.1; = p.N1066T on NM_000722.4) | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100665435; called by muse, mutect2, varscan2
- CACNB1 | c.1732G>C p.G578R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); catalogued as rs1192753272; called by muse, mutect2, varscan2
- CACNB3 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV56397488; called by muse, mutect2, varscan2
- CD1B | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.178); catalogued as COSV63805181; called by muse, mutect2, varscan2
- CD209 | c.1195C>A p.P399T | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.093); catalogued as rs752457226, COSV52657534; called by muse, mutect2, varscan2
- CDH15 | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.086); catalogued as rs1377931910; called by muse, mutect2, varscan2
- CDH4 | c.952A>T p.I318F | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs770821697; called by muse, mutect2, varscan2
- CDH9 | c.1838C>A p.T613K | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV50281922; called by muse, mutect2, varscan2
- CDK5RAP1 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 92/313 reads (29%) | catalogued as COSV59429572; called by muse, mutect2, varscan2
- CDK8 | c.475G>T p.V159F | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101037461; called by muse, mutect2, varscan2
- CEACAM4 | c.487G>T p.G163W | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99700852; called by muse, mutect2, varscan2
- CFAP221 | c.2453G>T p.G818V | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54660440; called by muse, mutect2, varscan2
- CHD6 | c.6013G>T p.E2005* | Nonsense Mutation (SNP) | VAF 20/181 reads (11%) | catalogued as COSV64688777; called by muse, mutect2, varscan2
- CHD7 | c.4765G>A p.A1589T | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1432652391; called by muse, mutect2, varscan2
- CHFR | c.976G>A p.A326T (on ENST00000432561 / NM_001161345.1; = p.A285T on NM_018223.2) | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs754144763; called by muse, mutect2, varscan2
- CHRNB3 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767219331, COSV99251628; called by muse, mutect2, varscan2
- CILP2 | c.2632G>T p.V878L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs1363047811, COSV52272562; called by muse, mutect2, varscan2
- CLEC7A | c.454G>T p.G152C (on ENST00000304084 / NM_197947.3; = p.G106C on NM_022570.5) | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV53723295; called by muse, mutect2
- CLIC1 | c.206A>G p.Y69C | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs747988662; called by muse, mutect2
- CNGA3 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV55622229; called by muse, mutect2, varscan2
- CNTN6 | c.2420G>C p.R807T | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV63176789; called by muse, mutect2, varscan2
- CNTNAP2 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV100671653; called by muse, mutect2, varscan2
- CNTNAP2 | c.3922G>A p.D1308N | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV100673259; called by muse, mutect2
- COL12A1 | c.3407G>C p.G1136A | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV59391821; called by muse, mutect2
- COL1A2 | c.2773G>A p.G925S | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM062559; called by muse, mutect2, varscan2
- COL24A1 | c.3682-1G>A p.X1228_splice | Splice Site (SNP) | VAF 7/82 reads (9%) | catalogued as rs1267789989; called by muse, mutect2
- COL5A3 | c.4152G>T p.L1384= | Splice Region (SNP) | VAF 4/21 reads (19%) | catalogued as rs941784706; called by muse, varscan2
- CPO | c.819G>T p.K273N | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs896000260, COSV55940880; called by muse, mutect2
- CRACD | c.2147A>C p.N716T | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as COSV51719546; called by muse, mutect2
- CSRP2 | c.282-2A>G p.X94_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | catalogued as rs1298086666; called by muse, mutect2
- CTNNA2 | c.347C>A p.S116* | Nonsense Mutation (SNP) | VAF 16/106 reads (15%) | catalogued as COSV63547968; called by muse, varscan2
- CYP2A6 | c.367C>A p.R123S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV99991697; called by muse, mutect2
- CYP2C19 | c.16G>T p.V6F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.114); catalogued as rs1172020609; called by muse, mutect2, varscan2
- CYTH2 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as rs916982857; called by muse, mutect2, varscan2
- DCC | c.2657G>T p.R886I | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as rs761365468, COSV59098644; called by muse, mutect2, varscan2
- DISP2 | c.795G>T p.M265I | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.892); catalogued as COSV51116544; called by muse, mutect2, varscan2
- DMD | c.2038A>G p.T680A | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.835); catalogued as rs200504614, COSV55878892; called by muse, mutect2, varscan2
- DMTF1 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as rs181048450; called by muse, mutect2, varscan2
- DNAH9 | c.8479G>T p.G2827C | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774998809; called by muse, mutect2, varscan2
- DNLZ | c.190G>C p.V64L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as rs368570491; called by mutect2, varscan2
- DOCK8 | c.2432G>T p.G811V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV101209930; called by muse, mutect2, varscan2
- DOCK8 | c.4376G>T p.G1459V | Missense Mutation (SNP) | VAF 48/278 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV66617736, COSV66623787; called by mutect2, varscan2
- DPH1 | c.301G>T p.V101L | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV99559747; called by muse, mutect2, varscan2
- DPP6 | c.2294G>T p.R765I (on ENST00000377770 / NM_001364500.2; = p.R703I on NM_001936.5) | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.949); catalogued as COSV100127388; called by muse, mutect2, varscan2
- DUSP19 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.199); catalogued as rs771489024; called by mutect2, varscan2
- EBF4 | c.364C>T p.R122W (on ENST00000609451; = p.R118W on NM_001110514.1) | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61355457; called by muse, mutect2, varscan2
- EIF3A | c.3137G>T p.R1046L | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV64961585; called by muse, mutect2, varscan2
- EMC6 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528793612; called by muse, mutect2
- ENPP2 | c.1060G>T p.V354F (on ENST00000075322 / NM_001040092.3; = p.V406F on NM_006209.5) | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV50012233; called by muse, mutect2, varscan2
- EPHA1 | c.1996C>A p.Q666K | Missense Mutation (SNP) | VAF 51/282 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV99315058; called by muse, mutect2, varscan2
- EPHA10 | c.1681del p.D561Tfs*10 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | catalogued as COSV57623363; called by mutect2, pindel
- EPHA5 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99901109; called by muse, mutect2, varscan2
- EPHB1 | c.759C>A p.C253* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV101213017; called by muse, varscan2
- EXO1 | c.937G>C p.A313P | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62218960; called by muse, mutect2, varscan2
- FAM107B | c.200C>A p.P67Q | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.238); catalogued as COSV99474103; called by muse, mutect2, varscan2
- FAM47B | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1451990651; called by muse, mutect2, varscan2
- FCRL3 | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as COSV63845343; called by muse, mutect2
- FGF10 | c.237G>A p.W79* | Nonsense Mutation (SNP) | VAF 31/256 reads (12%) | catalogued as CM163177; called by muse, mutect2, varscan2
- FPR1 | c.850G>C p.D284H | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV100494080, COSV59050974; called by muse, mutect2, varscan2
- FRMPD4 | c.1096C>A p.L366I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.627); catalogued as COSV66212135; called by muse, mutect2, varscan2
- FSIP2 | c.636T>A p.S212R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV58090790; called by muse, mutect2, varscan2
- FXR1 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 44/345 reads (13%) | catalogued as COSV59761956; called by muse, mutect2, varscan2
- GALNT17 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV61149754; called by muse, mutect2, varscan2
- GAMT | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs540554423; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GJA8 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM135086; called by muse, mutect2
- GON4L | c.4211C>G p.T1404R | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.051); catalogued as rs750025611; called by muse, mutect2, varscan2
- GPATCH8 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100132757; called by muse, mutect2, varscan2
- GPR17 | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV55753938, COSV55755380; called by mutect2, varscan2
- GPR55 | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV67408185; called by muse, mutect2, varscan2
- GRAMD2A | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748295237; called by muse, mutect2, varscan2
- GRIN2B | c.4103G>T p.G1368V | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.775); catalogued as COSV101662897; called by muse, mutect2, varscan2
- GRIN3B | c.2962C>G p.R988G | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1388402484; called by muse, varscan2
- H3C11 | c.52C>A p.R18S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.13); catalogued as COSV100138083; called by muse, mutect2, varscan2
- HIVEP1 | c.1519G>T p.D507Y | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101045069; called by muse, mutect2, varscan2
- HMBS | c.259A>G p.K87E | Missense Mutation (SNP) | VAF 16/377 reads (4%) | SIFT tolerated (0.87); PolyPhen benign (0.174); catalogued as COSV53827579; called by muse, mutect2
- HMCN1 | c.6395del p.P2132Hfs*7 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | catalogued as COSV54885346; called by mutect2, pindel, varscan2
- HOXD3 | c.274C>G p.R92G | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV50885832; called by muse, mutect2
- HTR2C | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.996); catalogued as rs781807542; called by muse, mutect2, varscan2
- HYAL4 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.745); catalogued as COSV99772452; called by muse, mutect2, varscan2
- IGLV5-45 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 43/441 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as rs1187796483; called by muse, mutect2
- ILDR2 | c.949A>G p.K317E | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1369429236; called by muse, mutect2, varscan2
- IPO13 | c.2581G>T p.D861Y | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54838596; called by muse, mutect2, varscan2
- IRS1 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV59338595; called by muse, mutect2, varscan2
- IRS4 | c.2446C>G p.R816G | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV64534766; called by muse, mutect2, varscan2
- IRX6 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as rs747111124; called by mutect2, varscan2
- ISL2 | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); catalogued as COSV99320888; called by muse, mutect2, varscan2
- ISLR | c.784C>A p.Q262K | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.381); catalogued as rs781552657; called by muse, mutect2, varscan2
- IVL | c.938T>G p.L313R | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.748); catalogued as COSV100908317; called by muse, mutect2
- JAML | c.596G>A p.W199* (on ENST00000356289 / NM_001098526.2; = p.W189* on NM_153206.3) | Nonsense Mutation (SNP) | VAF 34/252 reads (13%) | catalogued as rs1307595963; called by muse, mutect2, varscan2
- KBTBD12 | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 7/153 reads (5%) | catalogued as COSV59681058; called by muse, mutect2
- KCNA6 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54974938; called by muse, mutect2, varscan2
- KCNB1 | c.801G>T p.L267F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as rs1264980074; called by muse, mutect2
- KCNB1 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV65568401; called by muse, mutect2, varscan2
- KCNB2 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73053367; called by muse, mutect2, varscan2
- KCNC2 | c.982T>G p.L328V | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.163); catalogued as COSV100128080, COSV54363660; called by muse, mutect2
- KCNIP1 | c.50G>C p.R17P | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV61083560; called by muse, mutect2, varscan2
- KCNT1 | c.454G>T p.E152* (on ENST00000488444; = p.E171* on NM_020822.3) | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV53701283; called by muse, mutect2, varscan2
- KEAP1 | c.597G>T p.L199F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99407887; called by muse, varscan2
- KIF18B | c.2550G>T p.K850N | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as rs1293334277; called by muse, mutect2, varscan2
- KIF5A | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1203347152, COSV99672714; called by muse, mutect2, varscan2
- KIR3DL1 | c.770G>C p.R257T | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs1327594982; called by muse, mutect2, varscan2
- KLHDC7A | c.2191del p.R731Gfs*7 | Frame Shift Del (DEL) | VAF 21/130 reads (16%) | catalogued as COSV68770771; called by mutect2, pindel, varscan2
- KLHL40 | c.1504C>A p.L502I | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); catalogued as rs766195312; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KNDC1 | c.3956G>T p.S1319I | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1398873556; called by muse, mutect2, varscan2
- KPRP | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs763096836, COSV64221165, COSV64221618; called by muse, mutect2, varscan2
- LEP | c.22G>C p.G8R | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV58241071; called by muse, mutect2, varscan2
- LILRA4 | c.803G>T p.G268V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.859); catalogued as rs1166128894; called by muse, varscan2
- LILRB1 | c.2085C>A p.Y695* (on ENST00000427581; = p.Y644* on NM_006669.6) | Nonsense Mutation (SNP) | VAF 4/49 reads (8%) | catalogued as rs1395375851, COSV100207047; called by muse, mutect2
- LRCH2 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100407800; called by muse, mutect2, varscan2
- LRRC7 | c.3647C>A p.S1216* (on ENST00000651989 / NM_001370785.2; = p.S1183* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 17/101 reads (17%) | catalogued as COSV50611348; called by muse, mutect2, varscan2
- LRRC9 | c.2717A>C p.E906A | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.639); catalogued as COSV54290546; called by muse, mutect2, varscan2
- MACF1 | c.4390A>T p.I1464F | Missense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV58371208; called by muse, mutect2, varscan2
- MAGI2 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as rs147595175; called by muse, mutect2, varscan2
- MAN2B1 | c.2397G>T p.Q799H | Missense Mutation (SNP) | VAF 75/263 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1568298457, COSV55470106; called by muse, mutect2, varscan2
- MAP2K1 | c.729G>T p.Q243H | Missense Mutation (SNP) | VAF 69/352 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs772752167; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP7D2 | c.1542G>T p.K514N | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65526513; called by muse, mutect2, varscan2
- MDH1B | c.23-1G>T p.X8_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as COSV52700203; called by muse, mutect2
- MEOX2 | c.439G>T p.G147W | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV56288631; called by muse, varscan2
- METTL14 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV66311052; called by muse, mutect2, varscan2
- MGAM | c.4476del p.T1493Hfs*8 | Frame Shift Del (DEL) | VAF 14/101 reads (14%) | catalogued as COSV72075404; called by mutect2, pindel, varscan2
- MGAM | c.5239G>C p.G1747R | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs768304137; called by muse, varscan2
- MINK1 | c.823C>A p.L275M | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.025); catalogued as COSV61790069, COSV61793439; called by mutect2, varscan2
- MLLT6 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.311); catalogued as rs534291883; called by muse, mutect2, varscan2
- MROH2B | c.4487A>C p.K1496T | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV101270987; called by muse, mutect2
- MTCL1 | c.1808G>C p.R603P (on ENST00000306329 / NM_001378206.1; = p.R243P on NM_015210.4) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60406815; called by muse, mutect2, varscan2
- MTTP | c.1503C>A p.S501R | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774829310; called by muse, mutect2, varscan2
- MUC16 | c.38616G>C p.M12872I | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.235); catalogued as rs776256728, COSV67476401; called by muse, mutect2, varscan2
- MUC16 | c.17552C>A p.P5851H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as COSV101200752, COSV67494343; called by muse, mutect2, varscan2
- MUC16 | c.17551C>A p.P5851T | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.432); catalogued as COSV67460962; called by muse, mutect2, varscan2
- MUC16 | c.17371G>C p.E5791Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.01); catalogued as COSV67482797; called by muse, mutect2, varscan2
- MUC5B | c.16328C>T p.S5443L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as rs781648552; called by muse, mutect2, varscan2
- MUCL3 | c.845T>C p.L282P | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs868569774; called by mutect2, varscan2
- MYH13 | c.1482C>A p.H494Q | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV52840362; called by muse, mutect2
- MYLK2 | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 42/548 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.302); catalogued as COSV65658871; called by muse, mutect2
- MYO18B | c.7190C>G p.P2397R | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.804); catalogued as rs1426442407; called by muse, mutect2, varscan2
- MYOCD | c.2384C>A p.P795H | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV58501301; called by muse, mutect2, varscan2
- NEB | c.10304C>T p.P3435L | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs752318455, COSV51435457; called by muse, mutect2
- NLGN3 | c.2099A>C p.N700T (on ENST00000358741 / NM_181303.2; = p.N680T on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV62441434; called by muse, mutect2
- NLRP5 | c.2616-1G>T p.X872_splice | Splice Site (SNP) | VAF 16/66 reads (24%) | catalogued as COSV66763795, COSV66766236; called by muse, mutect2, varscan2
- NOTCH2 | c.1754A>T p.Q585L | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.088); catalogued as COSV56694394; called by muse, varscan2
- NPAS3 | c.111C>A p.D37E | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.964); catalogued as COSV58081493; called by muse, mutect2, varscan2
- NPVF | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs778264766; called by muse, mutect2, varscan2
- OBSCN | c.3394G>T p.V1132L | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.783); catalogued as rs747695006, COSV52833542; called by muse, mutect2, varscan2
- OR10G7 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV57868784; called by muse, mutect2
- OR10K2 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as rs754059809, COSV59220303; called by muse, mutect2, varscan2
- OR1E1 | c.802A>T p.T268S | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as COSV59459295; called by muse, mutect2, varscan2
- OR2A5 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV68738796; called by muse, mutect2, varscan2
- OR2T4 | c.602G>C p.R201P | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV63543315; called by muse, mutect2, varscan2
- OR4A5 | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.071); catalogued as COSV60524522; called by muse, mutect2
- OR4F15 | c.788C>A p.P263H | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); catalogued as COSV59969536; called by muse, mutect2, varscan2
- OR4N2 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.094); catalogued as COSV60050764; called by muse, mutect2, varscan2
- OR51B4 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs142325891; called by muse, mutect2, varscan2
- OR5B12 | c.807C>A p.D269E | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as COSV100222434; called by muse, mutect2
- OR5M1 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV101591540; called by muse, mutect2, varscan2
- OR5R1 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56573906; called by muse, mutect2, varscan2
- OR8G5 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV100422263, COSV100422627, COSV100422691; called by muse, mutect2, varscan2
- PABPC1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100589392, COSV59400103; called by muse, mutect2
- PCDH11X | c.3985C>G p.R1329G | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV104403083; called by muse, mutect2, varscan2
- PCDH15 | c.5632G>T p.E1878* | Nonsense Mutation (SNP) | VAF 31/264 reads (12%) | catalogued as COSV57332938, COSV57416693; called by muse, mutect2, varscan2
- PCDHB11 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.471); catalogued as COSV53384425; called by muse, mutect2, varscan2
- PCDHB7 | c.2023G>T p.E675* | Nonsense Mutation (SNP) | VAF 11/131 reads (8%) | catalogued as COSV50757471; called by muse, mutect2
- PDE1B | c.1558G>T p.A520S | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs774116556; called by muse, mutect2, varscan2
- PDE7B | c.127C>G p.R43G | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as rs367675238; called by muse, mutect2, varscan2
- PGA5 | c.856C>A p.P286T | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1204077188; called by muse, varscan2
- PJA2 | c.193G>C p.V65L | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.542); catalogued as COSV63275213; called by muse, mutect2, varscan2
- PKP4 | c.1333A>C p.T445P | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.719); catalogued as rs781212544; called by mutect2, varscan2
- PLEC | c.5276G>T p.R1759L (on ENST00000322810 / NM_201380.4; = p.R1649L on NM_000445.5) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.396); catalogued as COSV59616329; called by muse, mutect2, varscan2
- PLEKHG3 | c.895A>G p.R299G (on ENST00000394691; = p.R355G on NM_001308147.2) | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs937043063; called by muse, mutect2, varscan2
- PNMA8A | c.266G>C p.R89T | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as rs745957938, COSV58139045; called by muse, mutect2, varscan2
- POLE | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.006); catalogued as rs1060500817, COSV57684755; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPARG | c.235G>T p.E79* (on ENST00000287820 / NM_015869.5; = p.E49* on NM_005037.7) | Nonsense Mutation (SNP) | VAF 23/169 reads (14%) | catalogued as COSV55142138; called by muse, mutect2, varscan2
- PPP1R13L | c.2281G>T p.G761W | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100714715, COSV62907873; called by muse, mutect2, varscan2
- PRDM9 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 104/231 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1376126364, COSV57007198; called by muse, mutect2, varscan2
- PREX1 | c.1252C>T p.H418Y | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs954829643; called by muse, mutect2
- PROM1 | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV101477050; called by muse, mutect2, varscan2
- PTER | c.575C>G p.A192G | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV54347229; called by muse, mutect2
- PTPRB | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV99716780; called by muse, mutect2, varscan2
- PTPRT | c.3379G>T p.V1127L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100624258, COSV62017135; called by muse, mutect2, varscan2
- PXMP4 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 33/266 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV54132762, COSV54133884; called by muse, mutect2, varscan2
- RB1 | c.2212-2A>T p.X738_splice | Splice Site (SNP) | VAF 21/105 reads (20%) | catalogued as CS083262, COSV57307485, COSV99926008; called by muse, mutect2, varscan2
- RBM45 | c.1156G>C p.A386P (on ENST00000616198 / NM_001365579.1; = p.A384P on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99617866; called by muse, mutect2
- RBMS1 | c.571A>T p.T191S | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV100816648; called by muse, mutect2, varscan2
- RBMXL2 | c.889G>C p.G297R | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); catalogued as COSV60978794; called by muse, mutect2, varscan2
- REG4 | c.181T>C p.Y61H | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs771774182; called by muse, mutect2, varscan2
- RESP18 | c.233-8G>T | Splice Region (SNP) | VAF 10/95 reads (11%) | catalogued as rs779023462; called by muse, mutect2, varscan2
- RGS9 | c.185G>C p.R62P | Missense Mutation (SNP) | VAF 85/386 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52229942; called by muse, mutect2, varscan2
- RIMBP2 | c.1684G>T p.V562L | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.943); catalogued as COSV55482793; called by muse, mutect2, varscan2
- RNF32 | c.720C>A p.Y240* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as rs779157237; called by muse, mutect2, varscan2
- ROR2 | c.794G>C p.R265P | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV65218647; called by muse, mutect2, varscan2
- SCN4A | c.3897C>A p.N1299K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1342867575; called by muse, mutect2, varscan2
- SDK2 | c.4102G>T p.E1368* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | catalogued as COSV66190756; called by muse, mutect2, varscan2
- SEMA6C | c.2743G>T p.G915W | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.435); catalogued as rs780448271; called by muse, mutect2, varscan2
- SH2D1A | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.88); PolyPhen benign (0.009); catalogued as COSV100758262; called by muse, mutect2, varscan2
- SH3PXD2B | c.1292G>T p.R431L (on ENST00000636523; = p.R417L on NM_001308175.1) | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.3); catalogued as COSV101593607; called by muse, mutect2, varscan2
- SI | c.4141T>G p.F1381V | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.326); catalogued as COSV52265707; called by muse, mutect2
- SLC13A1 | c.1036C>G p.Q346E | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV52009408, COSV52014679; called by muse, mutect2, varscan2
- SLC1A3 | c.1026del p.N344Tfs*50 | Frame Shift Del (DEL) | VAF 41/259 reads (16%) | catalogued as COSV54317923, COSV99467569; called by mutect2, pindel, varscan2
- SLC26A5 | c.2066G>C p.R689P | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.342); catalogued as COSV59699682; called by muse, mutect2, varscan2
- SLC2A4RG | c.1103G>C p.R368P | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as rs143654337; called by muse, mutect2, varscan2
- SLC2A5 | c.1284G>T p.L428F | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.211); catalogued as COSV101072614; called by muse, mutect2, varscan2
- SLC4A1 | c.163C>A p.H55N | Missense Mutation (SNP) | VAF 72/386 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as CD972447; called by muse, mutect2, varscan2
- SMARCA4 | c.4636-2A>T p.X1546_splice | Splice Site (SNP) | VAF 51/244 reads (21%) | catalogued as rs372390180; called by muse, mutect2, varscan2
- SMR3A | c.205C>G p.P69A | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.051); catalogued as COSV56949592, COSV56950097; called by muse, mutect2, varscan2
- SORBS1 | c.2259G>T p.E753D (on ENST00000361941 / NM_001034954.2; = p.E500D on NM_024991.3 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53355216; called by muse, varscan2
- SPHK2 | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.614); catalogued as rs771069799; called by muse, mutect2, varscan2
- SSC5D | c.931C>A p.H311N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as rs1392156817; called by muse, mutect2, varscan2
- SSX2 | c.476G>C p.R159T (on ENST00000337502 / NM_175698.2; = p.G208R on NM_003147.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs1402397153; called by muse, mutect2, varscan2
- ST3GAL2 | c.175C>G p.R59G | Missense Mutation (SNP) | VAF 31/107 reads (29%) | PolyPhen benign (0.334); catalogued as COSV61595855, COSV61596917; called by muse, mutect2, varscan2
- STAG2 | c.934A>T p.I312F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV54366630; called by muse, mutect2, varscan2
- STPG1 | c.709A>T p.T237S (on ENST00000337248 / NM_001199013.2; = p.T190S on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV50217595; called by muse, mutect2, varscan2
- SUSD6 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV61364995; called by muse, mutect2, varscan2
- SYT12 | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV67354486; called by muse, varscan2
- TAS2R16 | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99972312; called by muse, mutect2, varscan2
- TDRD15 | c.4480G>C p.D1494H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.377); catalogued as COSV68267642; called by muse, mutect2, varscan2
- TECRL | c.431C>G p.T144S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.091); catalogued as COSV67087588; called by muse, mutect2
- TELO2 | c.163G>T p.A55S | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs769461559; called by muse, mutect2, varscan2
- TIMM44 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as COSV99563926; called by muse, mutect2, varscan2
- TMEM132C | c.1016C>A p.T339N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.527); catalogued as COSV59412759; called by muse, mutect2, varscan2
- TMEM26 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.752); catalogued as COSV53262105; called by muse, mutect2, varscan2
- TMEM260 | c.1601del p.K534Rfs*14 | Frame Shift Del (DEL) | VAF 17/172 reads (10%) | catalogued as rs1367949978; called by mutect2, pindel
- TMPRSS3 | c.45C>A p.F15L | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.97); catalogued as COSV99367704; called by muse, mutect2, varscan2
- TMTC1 | c.1057C>G p.R353G (on ENST00000539277 / NM_001193451.2; = p.R245G on NM_175861.3) | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55474854; called by muse, mutect2, varscan2
- TNPO2 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs369773308; called by muse, mutect2, varscan2
- TOGARAM1 | c.3673G>C p.G1225R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV100818025; called by muse, mutect2
- TRIM21 | c.990G>T p.M330I | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV99587931; called by muse, mutect2, varscan2
- TRIM7 | c.1243C>A p.R415S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV51241091; called by muse, mutect2, varscan2
- TRPM3 | c.1465G>T p.E489* (on ENST00000357533 / NM_001366142.2; = p.E334* on NM_020952.6) | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV100676676, COSV100678844; called by muse, mutect2, varscan2
- TRPV2 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs759931915; called by muse, mutect2, varscan2
- TTC5 | c.1000G>T p.G334C | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51871624; called by muse, mutect2, varscan2
- TTN | c.62682C>G p.S20894R (on ENST00000591111; = p.S13470R on NM_003319.4) | Missense Mutation (SNP) | VAF 30/197 reads (15%) | PolyPhen benign (0.007); catalogued as rs750847940, COSV59892746; called by muse, mutect2, varscan2
- TTN | c.46060G>T p.V15354F (on ENST00000591111; = p.V7930F on NM_003319.4) | Missense Mutation (SNP) | VAF 23/111 reads (21%) | PolyPhen benign (0); catalogued as rs187763563; called by muse, mutect2, varscan2
- TTN | c.44888G>T p.G14963V (on ENST00000591111; = p.G7539V on NM_003319.4) | Missense Mutation (SNP) | VAF 18/114 reads (16%) | PolyPhen probably damaging (0.956); catalogued as COSV60244857; called by muse, mutect2, varscan2
- TULP3 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs529548720, COSV68117655, COSV68118477; called by muse, mutect2, varscan2
- TXNDC5 | c.413+1G>T p.X138_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | catalogued as COSV65730663; called by muse, mutect2, varscan2
- UGGT2 | c.3642A>G p.K1214= | Splice Region (SNP) | VAF 13/92 reads (14%) | catalogued as COSV100948638; called by muse, mutect2, varscan2
- UNC79 | c.5272G>C p.E1758Q (on ENST00000393151 / NM_001346218.2; = p.E1581Q on NM_020818.5) | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.51); catalogued as rs776833151, COSV56395036; called by muse, mutect2, varscan2
- USH2A | c.5285C>A p.P1762H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV56439680; called by muse, mutect2, varscan2
- USP5 | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 37/246 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.31); catalogued as COSV57536570; called by muse, mutect2, varscan2
- VGLL1 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65703226; called by muse, mutect2, varscan2
- VWC2L | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.94); catalogued as COSV56965803; called by muse, mutect2, varscan2
- ZBTB20 | c.1507G>T p.A503S (on ENST00000474710 / NM_001164342.2; = p.A430S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/283 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV61872464; called by muse, mutect2, varscan2
- ZDBF2 | c.3667C>T p.L1223F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.88); catalogued as COSV100984712; called by muse, mutect2, varscan2
- ZEB1 | c.336C>A p.C112* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV58036207; called by muse, mutect2, varscan2
- ZGRF1 | c.6288G>T p.E2096D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1297217960; called by mutect2, varscan2
- ZMYM2 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as rs1278812459; called by muse, mutect2, varscan2
- ZNF133 | c.1006A>T p.S336C (on ENST00000316358 / NM_001352454.2; = p.S335C on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs147451613; called by muse, mutect2, varscan2
- ZNF140 | c.823T>C p.C275R | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1050031618; called by muse, mutect2, varscan2
- ZNF25 | c.327G>T p.Q109H | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV56924114; called by muse, varscan2
- ZNF429 | c.1180G>T p.E394* | Nonsense Mutation (SNP) | VAF 39/112 reads (35%) | catalogued as COSV100641815; called by muse, mutect2, varscan2
- ZNF518B | c.1407G>T p.L469F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as rs763767909, COSV58725201; called by muse, varscan2
- ZNF536 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.738); catalogued as rs772563038, COSV62821898, COSV62827945; called by muse, mutect2, varscan2
- ZNF599 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs757736464; called by muse, mutect2, varscan2
- ZNF683 | c.1265G>T p.G422V (on ENST00000403843; = p.G402V on NM_173574.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100853708; called by muse, mutect2, varscan2
- ZNF80 | c.322G>T p.V108L | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100351967; called by muse, mutect2, varscan2
- A2ML1 | c.2318C>A p.S773* | Nonsense Mutation (SNP) | VAF 63/340 reads (19%) | called by muse, mutect2, varscan2
- AADACL2 | c.27dup p.L10Afs*19 | Frame Shift Ins (INS) | VAF 11/83 reads (13%) | called by mutect2, pindel, varscan2
- ABCA13 | c.13432G>T p.V4478L | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCA13 | c.14847T>G p.D4949E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.437); called by muse, mutect2
- ABCA2 | c.2614A>T p.K872* (on ENST00000614293; = p.K842* on NM_001606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- ABCC2 | c.632+5G>T | Splice Region (SNP) | VAF 45/174 reads (26%) | called by muse, mutect2, varscan2
- ABCC2 | c.891G>T p.K297N | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABLIM3 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACE | c.2722G>T p.E908* | Nonsense Mutation (SNP) | VAF 24/158 reads (15%) | called by muse, mutect2, varscan2
- ACOT7 | c.743G>C p.G248A (on ENST00000377855 / NM_181864.3; = p.G238A on NM_007274.4) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACOX1 | c.260G>T p.W87L | Missense Mutation (SNP) | VAF 62/310 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ADAM22 | c.89A>T p.D30V | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM23 | c.2255G>T p.S752I | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADAMTS2 | c.1775A>T p.H592L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- ADAMTS20 | c.3823G>T p.V1275L | Missense Mutation (SNP) | VAF 20/243 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.026); called by muse, mutect2
- ADAMTS9 | c.4018T>A p.C1340S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTSL3 | c.4664G>T p.G1555V | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ADGRB3 | c.2531C>G p.T844S | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- ADGRG7 | c.628C>A p.Q210K | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- AFF3 | c.2171G>T p.G724V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- AFG3L2 | c.59A>G p.Q20R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGBL3 | c.2168A>G p.K723R | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.21); called by muse, mutect2
- AGO2 | c.51del p.I18Sfs*121 | Frame Shift Del (DEL) | VAF 11/67 reads (16%) | called by mutect2, pindel
- AHNAK | c.10595A>G p.K3532R | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- AKAP6 | c.5415G>C p.W1805C | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AKAP7 | c.570C>A p.N190K | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.013); called by muse, mutect2
- AL359922.1 | c.348-2A>G p.X116_splice | Splice Site (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- AL445989.1 | c.319G>C p.G107R | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT tolerated, low confidence (0.11); called by muse, mutect2, varscan2
- ALDH4A1 | c.454-2A>T p.X152_splice | Splice Site (SNP) | VAF 21/138 reads (15%) | called by muse, mutect2, varscan2
- ALMS1 | c.3338A>G p.E1113G | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALPP | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- AMACR | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- AMACR | c.682G>T p.G228W | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AMOT | c.3007G>T p.A1003S (on ENST00000371959 / NM_001113490.1; = p.A594S on NM_133265.3) | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ANKRD24 | c.2710G>T p.E904* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- ANKRD45 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANO2 | c.100C>G p.L34V (on ENST00000356134 / NM_001278597.3; = p.L38V on NM_001278596.3) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.344); called by muse, mutect2
- ANO3 | c.2330T>A p.L777H | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANXA4 | c.487del p.D163Mfs*11 | Frame Shift Del (DEL) | VAF 10/114 reads (9%) | called by mutect2, varscan2
- AP000350.4 | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated, low confidence (0.19); called by muse, mutect2, varscan2
- AP4E1 | c.1288G>T p.V430F | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, varscan2
- APAF1 | c.2293G>T p.G765* (on ENST00000551964 / NM_181861.2; = p.G754* on NM_001160.3) | Nonsense Mutation (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2, varscan2
- APBA3 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 15/259 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- ARHGAP36 | c.753A>C p.L251F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- ARHGAP6 | c.1485G>C p.L495F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.383); called by muse, mutect2
- ARHGEF12 | c.2713G>T p.D905Y | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGEF33 | c.81G>T p.Q27H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARMH2 | c.635G>C p.G212A | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARMH2 | c.543G>T p.M181I | Missense Mutation (SNP) | VAF 31/330 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ARMH2 | c.369G>C p.Q123H | Missense Mutation (SNP) | VAF 28/307 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ASH2L | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ASIC3 | c.1592T>C p.L531P | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ASRGL1 | c.756G>T p.L252F | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ASXL3 | c.5944C>G p.H1982D | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ATMIN | c.2217G>C p.E739D | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.124); called by muse, mutect2
- ATP11B | c.2048G>T p.R683I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by mutect2, varscan2
- ATP13A5 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.644); called by mutect2, varscan2
- ATP5MC2 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.186); called by muse, mutect2
- ATP6V1C1 | c.676A>T p.N226Y | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- AURKC | c.622C>A p.P208T (on ENST00000302804 / NM_001015878.2; = p.P174T on NM_003160.3) | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- B4GALNT1 | c.1121T>C p.L374P | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BARHL2 | c.224C>A p.P75Q | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BMP4 | c.749A>G p.Q250R | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- BMP7 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- BNIP2 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BPI | c.1378A>C p.T460P (on ENST00000262865; = p.T456P on NM_001725.3) | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.113); called by muse, mutect2
- BPI | c.1438T>C p.F480L (on ENST00000262865; = p.F476L on NM_001725.3) | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BRD7 | c.887A>G p.K296R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BRINP1 | c.1461G>C p.E487D | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- BRWD3 | c.4441G>A p.D1481N | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTBD11 | c.2527C>A p.Q843K (on ENST00000280758 / NM_001018072.2; = p.Q380K on NM_001017523.2) | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- C10orf82 | c.559+5G>T | Splice Region (SNP) | VAF 19/103 reads (18%) | called by muse, mutect2, varscan2
- C11orf98 | c.287A>T p.E96V | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- C12orf56 | c.1723C>A p.L575I (on ENST00000543942 / NM_001170633.2; = p.L415I on NM_001099676.3) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C1orf167 | c.290G>T p.W97L | Missense Mutation (SNP) | VAF 43/192 reads (22%) | called by muse, mutect2, varscan2
- C1orf194 | c.115C>A p.Q39K (on ENST00000369948 / NM_001245025.3; = p.Q27K on NM_001122961.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- C20orf194 | c.2651G>T p.G884V | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C2CD5 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.091); called by muse, varscan2
- C3orf52 | c.355T>C p.C119R | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C6 | c.461G>C p.R154T | Missense Mutation (SNP) | VAF 14/367 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.055); called by muse, mutect2
- CACNA1C | c.2985G>C p.K995N | Missense Mutation (SNP) | VAF 13/261 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CACNA2D4 | c.2596T>C p.W866R | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- CCDC102B | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- CCDC106 | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 52/253 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CCDC136 | c.1869G>T p.E623D | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC178 | c.1892A>T p.K631I | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- CCDC62 | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2
- CCDC73 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 38/194 reads (20%) | called by muse, mutect2, varscan2
- CD180 | c.512C>A p.P171Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CD86 | c.64+2T>A p.X22_splice (on ENST00000330540 / NM_175862.5; = p.X16_splice on NM_006889.4) | Splice Site (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- CD8A | c.48C>A p.L16= | Splice Region (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
- CDA | c.265A>C p.S89R | Missense Mutation (SNP) | VAF 25/345 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- CDH16 | c.1397G>C p.G466A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH18 | c.368A>T p.H123L | Missense Mutation (SNP) | VAF 51/351 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- CDK13 | c.2397G>T p.M799I | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2
- CDK16 | c.1129A>G p.I377V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CDKN1B | c.575G>C p.G192A | Missense Mutation (SNP) | VAF 56/329 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CELA1 | c.77G>C p.G26A | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, varscan2
- CELA2B | c.424del p.L142Sfs*32 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by mutect2, varscan2
- CEP164 | c.2571G>T p.E857D | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- CFAP100 | c.1536C>A p.H512Q | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CFAP46 | c.6199C>A p.L2067M | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CFAP54 | c.1753G>T p.A585S | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.412); called by muse, varscan2
- CFLAR | c.608T>A p.L203H | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- CHD6 | c.7522G>T p.G2508C | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2
- CHIT1 | c.774C>A p.S258R | Missense Mutation (SNP) | VAF 21/265 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.414); called by muse, mutect2
- CHRD | c.2353T>C p.Y785H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- CITED2 | c.796A>T p.S266C | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CLCN1 | c.1957G>T p.E653* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | called by muse, varscan2
- CLCN2 | c.899-2A>G p.X300_splice | Splice Site (SNP) | VAF 39/237 reads (16%) | called by muse, mutect2, varscan2
- CLCN4 | c.308G>T p.C103F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLEC4F | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2
- CLEC5A | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.031); called by muse, mutect2
- CLEC5A | c.164C>A p.S55Y | Missense Mutation (SNP) | VAF 47/226 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.133); called by muse, mutect2
- CNKSR2 | c.223G>C p.A75P | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- CNTN1 | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- COL1A1 | c.3307G>T p.G1103C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL22A1 | c.1074C>A p.D358E | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- COL5A1 | c.795A>C p.E265D | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- COL5A2 | c.4379C>A p.T1460N | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- COL5A2 | c.1552G>T p.V518L | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- COL6A5 | c.5164-1G>T p.X1722_splice | Splice Site (SNP) | VAF 36/140 reads (26%) | called by muse, mutect2, varscan2
- COLEC11 | c.342G>C p.E114D | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.582); called by muse, mutect2
- COQ8B | c.892A>C p.R298= | Splice Region (SNP) | VAF 16/118 reads (14%) | called by muse, varscan2
- CPA4 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPNE8 | c.351T>G p.F117L | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- CPNE9 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CPOX | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- CPS1 | c.3617C>A p.A1206D | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPXM2 | c.1849C>A p.P617T | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRACR2A | c.659G>T p.C220F | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- CREB3L1 | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 21/123 reads (17%) | called by muse, mutect2, varscan2
- CREB3L3 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 17/221 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.084); called by muse, mutect2
- CRTC2 | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CSMD3 | c.5230G>C p.G1744R (on ENST00000297405 / NM_001363185.1; = p.G1640R on NM_052900.3) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CSTF2T | c.1291C>A p.R431S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CTCFL | c.117A>T p.K39N | Missense Mutation (SNP) | VAF 23/250 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.143); called by muse, mutect2
- CUBN | c.10720G>C p.G3574R | Missense Mutation (SNP) | VAF 51/405 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUBN | c.8752A>C p.S2918R | Missense Mutation (SNP) | VAF 29/342 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- CUBN | c.4274C>A p.P1425H | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUBN | c.2350A>T p.I784F | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CUBN | c.689G>T p.C230F | Missense Mutation (SNP) | VAF 96/375 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUTA | c.440A>T p.E147V (on ENST00000488034 / NM_001014840.2; = p.E124V on NM_015921.3) | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CXorf66 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); called by mutect2, varscan2
- CYB5D1 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- CYGB | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CYP4F2 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DCBLD2 | c.571+4A>G | Splice Region (SNP) | VAF 9/130 reads (7%) | called by muse, mutect2
- DCLRE1B | c.879G>T p.Q293H | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- DDX47 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); called by muse, mutect2
- DEGS2 | c.160C>A p.Q54K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DENND4A | c.3816G>T p.E1272D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2
- DGKI | c.704C>A p.T235K | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- DIRAS3 | c.446T>G p.L149R | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DMRTC2 | c.294C>A p.H98Q | Missense Mutation (SNP) | VAF 39/336 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- DMXL2 | c.2954C>A p.P985Q | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH9 | c.748G>T p.V250L | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.285); called by muse, mutect2
- DNAH9 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DNAJC6 | c.1970C>T p.T657I | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.795); called by muse, mutect2
- DOCK2 | c.2542T>C p.F848L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- DPY19L2 | c.861+2T>A p.X287_splice | Splice Site (SNP) | VAF 9/147 reads (6%) | called by muse, mutect2
- DRC7 | c.1308G>T p.K436N | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- DTNB | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUXB | c.467T>A p.L156Q | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.434); called by muse, varscan2
- DVL3 | c.707G>T p.S236I | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DYM | c.183C>G p.C61W | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2
- DYNC1H1 | c.8135G>C p.C2712S | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DYRK2 | c.1088G>A p.G363D (on ENST00000344096 / NM_006482.3; = p.G290D on NM_003583.4) | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DYSF | c.3844-7A>T | Splice Region (SNP) | VAF 49/236 reads (21%) | called by muse, mutect2, varscan2
- EFR3A | c.1528A>T p.I510L | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- EIF2AK3 | c.2128G>T p.E710* | Nonsense Mutation (SNP) | VAF 15/149 reads (10%) | called by muse, mutect2, varscan2
- EIF2AK3 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- EIF4G1 | c.2883G>C p.Q961H (on ENST00000346169 / NM_198241.3; = p.Q766H on NM_004953.5) | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2
- ELP4 | c.935A>T p.K312I (on ENST00000350638; = p.K311I on NM_019040.5) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2
- EML2 | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENPP1 | c.1606G>T p.G536C | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EPB41L1 | c.1011G>T p.K337N | Missense Mutation (SNP) | VAF 15/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPHA6 | c.2245A>T p.K749* (on ENST00000389672 / NM_001080448.3; = p.K141* on NM_173655.4) | Nonsense Mutation (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- EPHB6 | c.2047G>A p.G683R | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPX | c.1279C>A p.Q427K | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- EPYC | c.89C>A p.S30* | Nonsense Mutation (SNP) | VAF 44/220 reads (20%) | called by muse, varscan2
- ERBIN | c.1755G>C p.L585F | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ERICH6B | c.1931C>A p.P644H | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ERN1 | c.2887C>A p.H963N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ETS2 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 42/390 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); called by muse, mutect2
- EVC2 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FAM186A | c.569A>C p.Q190P | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by mutect2, varscan2
- FAM189A1 | c.160C>A p.L54M | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM83C | c.434A>T p.Q145L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- FANCG | c.1389G>T p.W463C | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- FAT1 | c.3579A>T p.T1193= | Splice Region (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- FBLN7 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 75/146 reads (51%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBN1 | c.3549C>A p.N1183K | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- FBRSL1 | c.2051G>T p.S684I | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FBXL15 | c.808G>T p.G270C | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FBXW10 | c.871+5G>T | Splice Region (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- FBXW7 | c.1453G>C p.V485L (on ENST00000281708 / NM_001349798.2; = p.V405L on NM_018315.5) | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.042); called by muse, mutect2
- FEM1B | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- FFAR2 | c.341C>G p.P114R | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGD4 | c.130G>C p.A44P | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- FHAD1 | c.646T>A p.Y216N | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- FKBP11 | c.493G>T p.V165L | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FLNA | c.490A>T p.K164* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- FOXI1 | c.11T>A p.F4Y | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, varscan2
- FRMD3 | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, varscan2
- FSTL5 | c.2193del p.F731Lfs*48 | Frame Shift Del (DEL) | VAF 32/93 reads (34%) | called by mutect2, pindel, varscan2
- G2E3 | c.2094A>T p.E698D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.15); called by muse, varscan2
- GABPA | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- GABRB3 | c.212G>T p.S71I | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GCNT7 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDF2 | c.122T>A p.L41Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GGTLC2 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GIMAP6 | c.433C>G p.R145G | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- GJA10 | c.957A>C p.K319N | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, varscan2
- GJB4 | c.77C>G p.S26C | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GJD4 | c.932G>T p.R311L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.08); called by mutect2, varscan2
- GLCE | c.467A>G p.H156R | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2
- GLI3 | c.1780G>C p.A594P | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2
- GLIS1 | c.1276T>A p.S426T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, varscan2
- GNAS | c.786G>T p.Q262H | Missense Mutation (SNP) | VAF 43/365 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GOLGB1 | c.2635G>T p.D879Y | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- GPR15 | c.1009C>A p.L337I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- GPRC5C | c.1273A>C p.K425Q (on ENST00000652232; = p.K380Q on NM_018653.4) | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- GRIP2 | c.1398C>A p.H466Q (on ENST00000619221; = p.H369Q on NM_001080423.4) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.211); called by mutect2, varscan2
- GTF3C1 | c.1705C>T p.H569Y | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.322); called by muse, mutect2
- HARBI1 | c.761_763delinsTT p.S254Ffs*6 | Frame Shift Del (DEL) | VAF 16/155 reads (10%) | called by pindel, varscan2*
- HDAC9 | c.656C>A p.A219D | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, varscan2
- HDAC9 | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- HECW1 | c.2115del p.S706Pfs*106 | Frame Shift Del (DEL) | VAF 19/169 reads (11%) | called by mutect2, pindel, varscan2
- HELZ | c.2178-1G>T p.X726_splice | Splice Site (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- HIVEP1 | c.5557A>C p.S1853R | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.062); called by muse, mutect2
- HOXA10 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- HOXC10 | c.863T>A p.L288Q | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HSD11B1 | c.306T>G p.F102L | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HSPA9 | c.1619G>T p.G540V | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA9 | c.1618G>T p.G540* | Nonsense Mutation (SNP) | VAF 28/190 reads (15%) | called by muse, mutect2, varscan2
- HSPG2 | c.8814A>T p.E2938D | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HTR1D | c.245C>A p.T82N | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, varscan2
- HTR1D | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 44/305 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, varscan2
- HUWE1 | c.6149G>C p.R2050P | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.174); called by mutect2, varscan2
- HYDIN | c.8051T>C p.M2684T | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- IDH3A | c.229A>T p.K77* | Nonsense Mutation (SNP) | VAF 32/235 reads (14%) | called by muse, mutect2, varscan2
- IGF2 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- IGF2R | c.7154G>T p.G2385V | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- IGFBP4 | c.362del p.G121Vfs*36 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- IGHV3-16 | c.161A>C p.N54T | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.009); called by muse, mutect2
- IGHV3-35 | c.142T>G p.F48V | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.304); called by muse, mutect2
- IGKV3D-20 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL10RA | c.937del p.L313Cfs*67 | Frame Shift Del (DEL) | VAF 23/189 reads (12%) | called by mutect2, pindel, varscan2
- IL36RN | c.266A>T p.Y89F | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- INAVA | c.1114G>T p.V372L | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- INPP5K | c.609C>A p.H203Q | Missense Mutation (SNP) | VAF 16/335 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2
- INPPL1 | c.2404C>T p.Q802* | Nonsense Mutation (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- INS-IGF2 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- INSR | c.2638C>G p.L880V | Missense Mutation (SNP) | VAF 40/257 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- IQSEC3 | c.2231T>A p.V744E (on ENST00000538872 / NM_001170738.2; = p.V441E on NM_015232.1) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ITGB1 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR2 | c.984A>T p.E328D | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2
- ITPRID1 | c.2807G>T p.R936I | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- JAK2 | c.2491G>T p.G831W | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KATNIP | c.2959del p.D987Tfs*10 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- KCNA6 | c.498C>A p.Y166* | Nonsense Mutation (SNP) | VAF 19/195 reads (10%) | called by muse, mutect2, varscan2
- KCNA6 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- KCNH7 | c.3346G>C p.E1116Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- KCNQ2 | c.864G>T p.W288C | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KDM1A | c.2552G>T p.S851I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- KDM7A | c.2417C>G p.S806C | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2
- KHDC3L | c.95C>A p.S32Y | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- KIF17 | c.2367T>A p.D789E | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIF21A | c.4704G>C p.W1568C (on ENST00000361418 / NM_001378440.1; = p.W1555C on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIR3DL2 | c.170A>C p.N57T | Missense Mutation (SNP) | VAF 35/482 reads (7%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.997); called by muse, mutect2
- KIR3DL3 | c.1129C>A p.Q377K | Missense Mutation (SNP) | VAF 53/266 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- KLHL28 | c.499G>T p.V167F | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- KLK15 | c.744G>A p.W248* | Nonsense Mutation (SNP) | VAF 22/79 reads (28%) | called by muse, mutect2, varscan2
- LEPR | c.1375G>T p.E459* | Nonsense Mutation (SNP) | VAF 37/256 reads (14%) | called by muse, mutect2, varscan2
- LGI1 | c.1216C>A p.Q406K | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LHCGR | c.1958G>A p.R653K | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- LHFPL3 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- LHX1 | c.685C>A p.Q229K | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by mutect2, varscan2
- LHX1 | c.686A>G p.Q229R | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- LILRA5 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); called by muse, mutect2
- LILRB5 | c.70+5G>C | Splice Region (SNP) | VAF 11/119 reads (9%) | called by muse, mutect2
- LNX2 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- LRRC3C | c.421G>T p.A141S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- LRRC69 | c.742T>A p.W248R | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- LRRC7 | c.243C>A p.N81K (on ENST00000651989 / NM_001370785.2; = p.N48K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- LY75 | c.3865A>G p.I1289V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- MACC1 | c.1820G>A p.G607E | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MACROD2 | c.1053C>G p.D351E (on ENST00000642719; = p.D323E on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.11); called by muse, varscan2
- MAGEB6 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MAGEB6B | c.775G>T p.G259C | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MAML1 | c.2752_2763del p.A918_P921del | In Frame Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel
- MAP3K13 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- MAP3K15 | c.3196G>T p.V1066L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MAPKAP1 | c.844del p.R282Efs*2 | Frame Shift Del (DEL) | VAF 3/17 reads (18%) | called by mutect2, pindel, varscan2
- MARF1 | c.2042A>C p.N681T | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MATN4 | c.630G>T p.Q210H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- MB21D2 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MCM10 | c.2384A>T p.E795V (on ENST00000484800 / NM_182751.3; = p.E794V on NM_018518.5) | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MFN2 | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- MGAT4C | c.880G>T p.G294C | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.631); called by muse, mutect2
- MIOX | c.763T>C p.Y255H | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMAA | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MMP9 | c.1639G>A p.G547R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, varscan2
- MMRN1 | c.1081G>T p.G361* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- MOGAT3 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, varscan2
- MORN5 | c.7T>A p.Y3N | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, varscan2
- MRC1 | c.1864A>C p.K622Q | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- MROH9 | c.1822C>G p.L608V | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.397); called by muse, mutect2
- MSC | c.498C>G p.D166E | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2
- MSGN1 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- MTERF3 | c.1059+1G>T p.X353_splice | Splice Site (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- MTMR1 | c.867+1G>T p.X289_splice | Splice Site (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- MTMR12 | c.2005G>T p.E669* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- MUC16 | c.17896del p.R5966Gfs*4 | Frame Shift Del (DEL) | VAF 25/108 reads (23%) | called by mutect2, pindel, varscan2
- MUC16 | c.4114A>G p.S1372G | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- MUC17 | c.2735C>A p.T912N | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- MUC5B | c.8120C>G p.S2707C | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MYCBP2 | c.12388C>A p.P4130T (on ENST00000357337; = p.P4168T on NM_015057.5) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.987); called by muse, varscan2
- MYCBP2 | c.10381C>T p.P3461S (on ENST00000357337; = p.P3499S on NM_015057.5) | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- MYH13 | c.5446A>T p.I1816F | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2
- MYH13 | c.2391G>T p.R797S | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYH8 | c.4946C>G p.T1649S | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- MYO15A | c.9577G>T p.E3193* | Nonsense Mutation (SNP) | VAF 62/241 reads (26%) | called by muse, mutect2, varscan2
- MYO9B | c.4168A>T p.K1390* | Nonsense Mutation (SNP) | VAF 31/136 reads (23%) | called by muse, mutect2, varscan2
- NAV3 | c.5565A>C p.E1855D (on ENST00000397909 / NM_001024383.2; = p.E1833D on NM_014903.6) | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.4); called by muse, mutect2
- NBEA | c.4603G>C p.D1535H | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- NBR1 | c.508del p.V170Lfs*88 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, varscan2
- NCAPD3 | c.126A>G p.I42M | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- NEFL | c.754C>A p.P252T | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEK10 | c.310A>C p.K104Q | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NFAT5 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); called by muse, mutect2
- NFRKB | c.71G>T p.R24L (on ENST00000446488 / NM_001143835.2; = p.R37L on NM_006165.3) | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NHLH2 | c.183G>T p.Q61H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- NIM1K | c.972G>T p.W324C | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NKX3-2 | c.198del p.E67Rfs*57 | Frame Shift Del (DEL) | VAF 10/61 reads (16%) | called by mutect2, pindel, varscan2
- NLRP14 | c.3181A>T p.K1061* | Nonsense Mutation (SNP) | VAF 15/201 reads (7%) | called by muse, mutect2
- NLRP2 | c.815A>G p.D272G | Missense Mutation (SNP) | VAF 15/312 reads (5%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.472); called by muse, mutect2
- NLRP3 | c.775T>A p.C259S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOC4L | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOS1 | c.1466G>C p.G489A | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NOS2 | c.2074A>T p.I692F | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.629); called by muse, mutect2
- NOTCH3 | c.2558G>T p.C853F | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NOX4 | c.1617-1G>C p.X539_splice | Splice Site (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- NPC1L1 | c.3885C>A p.D1295E | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- NPHS2 | c.1067G>T p.R356I | Missense Mutation (SNP) | VAF 108/201 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NPTX2 | c.787G>T p.G263C | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPTX2 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NQO1 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.409); called by muse, varscan2
- NR0B2 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NRG1 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.031); called by muse, mutect2
- NRK | c.4554G>T p.K1518N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- NRROS | c.844A>G p.N282D | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRXN1 | c.3329G>T p.S1110I | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NRXN2 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, varscan2
- NTNG1 | c.1232T>A p.L411Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- NUAK2 | c.1418A>T p.D473V | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- NUDT14 | c.491A>T p.Q164L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- OBSCN | c.20438C>A p.P6813Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OLFML3 | c.707A>T p.E236V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.025); called by muse, mutect2
- ONECUT3 | c.745G>C p.A249P | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.995); called by muse, varscan2
- OPN5 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 81/246 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- OR10H3 | c.244A>G p.M82V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OR10J5 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 13/213 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2
- OR14A2 | c.922G>A p.G308S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, varscan2
- OR14A2 | c.442G>C p.A148P | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); called by muse, varscan2
- OR1E2 | c.449G>A p.C150Y | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR1S1 | c.259A>T p.I87F | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- OR2A12 | c.65T>A p.L22Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- OR2A25 | c.312G>C p.L104F | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); called by muse, mutect2
- OR2F1 | c.74T>A p.V25D | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- OR2G3 | c.807C>G p.D269E | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- OR2L2 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- OR2T10 | c.611T>C p.V204A | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.19); called by muse, varscan2
- OR2W1 | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- OR2W3 | c.616G>T p.V206F | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4K15 | c.229T>C p.S77P (on ENST00000305051; = p.S53P on NM_001005486.1) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4M1 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR4Q3 | c.721G>T p.G241C | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- OR51A4 | c.609del p.F203Lfs*8 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, varscan2
- OR52I1 | c.170C>A p.S57Y | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- OR52I2 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 20/209 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.564); called by muse, mutect2
- OR6B3 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6Q1 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.146); called by muse, mutect2
- OR7D2 | c.287A>G p.D96G | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- OR9A4 | c.733T>A p.F245I | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- OR9Q1 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- OTX2 | c.701C>A p.S234Y (on ENST00000408990 / NM_172337.3; = p.S242Y on NM_021728.4) | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- P2RY12 | c.872C>G p.A291G | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PA2G4 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PADI3 | c.1277G>T p.G426V | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAGE4 | c.226G>T p.G76* | Nonsense Mutation (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2, varscan2
- PAGE4 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- PAK4 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- PAX6 | c.786G>T p.R262S | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PC | c.1610C>G p.P537R | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.097); called by muse, varscan2
- PCDH8 | c.2634del p.Y879Tfs*58 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel
- PCDHA10 | c.1890C>G p.I630M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PCDHAC1 | c.2180A>T p.Y727F | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PCDHB14 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- PCDHB8 | c.1877G>T p.R626L | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PCDHB8 | c.2002T>C p.S668P | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PCID2 | c.429G>C p.E143D | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2
- PCLO | c.14387G>C p.R4796T | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- PCLO | c.10685G>T p.G3562V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCNX2 | c.4605G>T p.K1535N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCNX4 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCSK4 | c.449A>T p.Q150L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PDE11A | c.2195C>A p.T732N | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PDE11A | c.358del p.E120Sfs*2 | Frame Shift Del (DEL) | VAF 26/187 reads (14%) | called by mutect2, pindel, varscan2
- PDE12 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE1C | c.1671A>C p.E557D | Missense Mutation (SNP) | VAF 26/347 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- PDZRN4 | c.1645C>A p.H549N (on ENST00000402685 / NM_001164595.2; = p.H291N on NM_013377.4) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHAX | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3R4 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PIK3R5 | c.1871G>A p.G624D | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PITRM1 | c.1305G>T p.Q435H | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- PIWIL4 | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- PKDREJ | c.1635T>A p.S545R | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- PKHD1 | c.3845C>T p.P1282L | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLCD4 | c.183C>G p.F61L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2
- PLPPR4 | c.1409G>A p.G470E | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); called by muse, mutect2
- PNLIPRP2 | c.204A>T p.Q68H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PNN | c.1871G>T p.S624I | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- POF1B | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- POF1B | c.198G>T p.L66F | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POLH | c.721G>T p.G241W | Missense Mutation (SNP) | VAF 580/867 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- POM121L2 | c.1137G>C p.W379C | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- PPARGC1A | c.1049del p.E350Gfs*61 | Frame Shift Del (DEL) | VAF 9/84 reads (11%) | called by mutect2, pindel, varscan2
- PPFIBP2 | c.965-1G>A p.X322_splice | Splice Site (SNP) | VAF 8/88 reads (9%) | called by muse, varscan2
- PPP1R26 | c.1119G>T p.Q373H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PRDM9 | c.2287C>A p.L763I | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.122); called by muse, varscan2
- PRKACA | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRPF6 | c.1927G>T p.E643* | Nonsense Mutation (SNP) | VAF 31/299 reads (10%) | called by muse, mutect2, varscan2
- PRRC2C | c.3901G>T p.V1301L (on ENST00000367742; = p.V1299L on NM_015172.4) | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRSS55 | c.479T>C p.L160P | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PSG11 | c.445C>G p.P149A | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSMA5 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PSME3IP1 | c.84G>T p.R28S | Missense Mutation (SNP) | VAF 72/300 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSTPIP2 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- PTF1A | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN5 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 26/155 reads (17%) | called by muse, mutect2, varscan2
- PTPRD | c.1768C>A p.P590T | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- PTPRF | c.4033A>T p.K1345* | Nonsense Mutation (SNP) | VAF 42/330 reads (13%) | called by muse, mutect2, varscan2
- PTPRT | c.2650G>T p.G884C | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PXDN | c.4190C>T p.T1397I | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2
- PYGM | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 25/320 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- RAB3C | c.257C>G p.T86R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB7A | c.479T>C p.I160T | Missense Mutation (SNP) | VAF 16/307 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.009); called by muse, mutect2
- RALGDS | c.2603A>G p.Y868C | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RANBP6 | c.397G>C p.G133R | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RANBP9 | c.1922A>G p.N641S | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); called by muse, mutect2
- RAX | c.1005C>G p.H335Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- RBM20 | c.3146C>A p.P1049H | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.834); called by muse, varscan2
- RDH16 | c.134T>A p.L45Q | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- RECK | c.523C>A p.P175T | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RELN | c.1143+1G>C p.X381_splice | Splice Site (SNP) | VAF 25/209 reads (12%) | called by muse, mutect2, varscan2
- RGCC | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- RGPD3 | c.3227A>G p.Q1076R | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); called by muse, mutect2
- RGPD4 | c.1556C>A p.P519H | Missense Mutation (SNP) | VAF 90/436 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- RHCE | c.1015G>T p.G339* | Nonsense Mutation (SNP) | VAF 33/265 reads (12%) | called by muse, mutect2, varscan2
- RHOH | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
594 further variants in this file (176 protein-altering or splice-affecting, 247 silent, 171 other) are not listed here.
